Somatic mutation profile of tumor specimen TCGA-24-2281-01A (aliquot TCGA-24-2281-01A-01W-0799-08) from TCGA case TCGA-24-2281, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIA; Tumor grade: G3; Age at diagnosis: 68.5 years (25,019 days).
Specimen TCGA-24-2281-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2886b69a-346f-495d-ab8b-5cb48fe3884c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-24-2281-10A (Blood Derived Normal), aliquot TCGA-24-2281-10A-01W-0799-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/336d2a96-5535-443b-8447-00993adfdf9c

The open-access MAF lists 61 somatic variants for this specimen: 47 protein-altering or splice-affecting, 13 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 38, Silent 13, Splice Site 2, Nonsense Mutation 2, Frame Shift Del 2, Nonstop Mutation 1, Frame Shift Ins 1, Splice Region 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.524G>A p.R175H | Missense Mutation (SNP) | VAF 201/318 reads (63%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.319); catalogued as rs28934578, CM062017, CM951224, COSV52661038, COSV52677601, COSV52731306, COSV53801286; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- ABCG4 | c.1604C>A p.T535N | Missense Mutation (SNP) | VAF 26/490 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.649); catalogued as COSV100266969; called by muse, mutect2
- ADAMTS3 | c.137C>A p.T46N | Missense Mutation (SNP) | VAF 9/188 reads (5%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.828); catalogued as COSV99711853; called by muse, mutect2
- ADGRL1 | c.2399C>A p.A800D (on ENST00000340736 / NM_001008701.3; = p.A795D on NM_014921.5) | Missense Mutation (SNP) | VAF 10/83 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.665); catalogued as COSV61564032; called by muse, mutect2
- ANKHD1 | c.1243-1G>T p.X415_splice | Splice Site (SNP) | VAF 20/141 reads (14%) | catalogued as COSV51843051; called by muse, varscan2
- ATP10B | c.3669T>G p.D1223E | Missense Mutation (SNP) | VAF 82/199 reads (41%) | SIFT deleterious (0.03); PolyPhen benign (0.017); catalogued as COSV59146574; called by muse, mutect2, varscan2
- ATP2A2 | c.1826C>A p.S609Y | Missense Mutation (SNP) | VAF 70/294 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV57875156; called by muse, mutect2, varscan2
- CCDC134 | c.199G>C p.D67H | Missense Mutation (SNP) | VAF 50/98 reads (51%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.987); catalogued as COSV55387728; called by muse, mutect2, varscan2
- CCDC134 | c.278G>A p.G93E | Missense Mutation (SNP) | VAF 22/58 reads (38%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.592); catalogued as COSV55387737; called by muse, mutect2, varscan2
- CCDC40 | c.2760G>A p.M920I | Missense Mutation (SNP) | VAF 36/72 reads (50%) | SIFT deleterious (0.02); PolyPhen benign (0.218); catalogued as COSV66473656; called by muse, mutect2, varscan2
- CCPG1 | c.1427G>T p.R476M | Missense Mutation (SNP) | VAF 26/563 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.847); catalogued as COSV99380648; called by muse, mutect2
- CEP192 | c.2415G>T p.M805I | Missense Mutation (SNP) | VAF 44/225 reads (20%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as COSV58061652; called by muse, mutect2, varscan2
- CHAF1A | c.1544G>A p.R515Q | Missense Mutation (SNP) | VAF 42/66 reads (64%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.999); catalogued as rs753288525, COSV56671035; called by muse, mutect2, varscan2
- CNTNAP4 | c.3859G>A p.A1287T | Missense Mutation (SNP) | VAF 35/58 reads (60%) | SIFT tolerated (0.75); PolyPhen benign (0); catalogued as COSV56671048; called by muse, mutect2, varscan2
- DYSF | c.1384C>T p.R462C | Missense Mutation (SNP) | VAF 19/165 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.969); catalogued as rs1192937487, COSV50280483; called by muse, mutect2, varscan2
- GRM5 | c.274G>C p.G92R | Missense Mutation (SNP) | VAF 39/94 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59596727, COSV59614892; called by muse, mutect2, varscan2
- INPP4A | c.2166C>T p.Y722= (on ENST00000074304 / NM_001134224.1; = p.Y683= on NM_001566.2 and 1 other RefSeq transcript) | Splice Region (SNP) | VAF 7/16 reads (44%) | catalogued as rs374744040; called by muse, mutect2, varscan2
- KIF3C | c.1771-1G>A p.X591_splice | Splice Site (SNP) | VAF 10/61 reads (16%) | catalogued as COSV53098307; called by muse, mutect2, varscan2
- KLHL22 | c.1405G>T p.G469C | Missense Mutation (SNP) | VAF 79/1017 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.332); catalogued as COSV100186202; called by muse, mutect2
- KNTC1 | c.197C>A p.S66* | Nonsense Mutation (SNP) | VAF 9/83 reads (11%) | catalogued as COSV100338091, COSV100338694; called by muse, mutect2, varscan2
- LIPE | c.2647G>A p.G883R | Missense Mutation (SNP) | VAF 31/65 reads (48%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.448); catalogued as rs145794577; called by muse, mutect2, varscan2
- LRP4 | c.4600G>A p.A1534T | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.678); catalogued as COSV66134761; called by muse, mutect2, varscan2
- LY9 | c.697T>A p.S233T | Missense Mutation (SNP) | VAF 63/375 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as COSV54432479; called by muse, mutect2, varscan2
- NME9 | c.482C>A p.T161N (on ENST00000333911 / NM_001349024.2; = p.T100N on NM_178130.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 62/236 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV100444870; called by muse, mutect2, varscan2
- OR6B3 | c.705G>T p.W235C | Missense Mutation (SNP) | VAF 37/85 reads (44%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.926); catalogued as COSV60113253; called by muse, mutect2, varscan2
- OTUD4 | c.3199G>T p.V1067L (on ENST00000447906 / NM_001366057.1; = p.V1002L on NM_001102653.1) | Missense Mutation (SNP) | VAF 119/1138 reads (10%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as COSV71381646; called by muse, mutect2, varscan2
- PAK6 | c.1491G>C p.R497S | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.993); catalogued as COSV53044845; called by muse, mutect2, varscan2
- PCDHGA9 | c.638C>T p.T213M | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.577); catalogued as COSV53917042; called by muse, mutect2, varscan2
- PDE3A | c.1754G>T p.C585F | Missense Mutation (SNP) | VAF 26/263 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.001); catalogued as COSV62969997; called by muse, mutect2, varscan2
- PGAP1 | c.1912A>G p.K638E | Missense Mutation (SNP) | VAF 40/98 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV61324804; called by muse, mutect2, varscan2
- POU2F3 | c.994C>T p.R332* | Nonsense Mutation (SNP) | VAF 14/68 reads (21%) | catalogued as rs762583643, COSV52792893, COSV99501315; called by muse, mutect2, varscan2
- PPARGC1B | c.572C>T p.P191L | Missense Mutation (SNP) | VAF 21/178 reads (12%) | SIFT tolerated (0.07); PolyPhen benign (0.007); catalogued as COSV58527404; called by muse, mutect2, varscan2
- RASSF8 | c.233G>A p.R78Q | Missense Mutation (SNP) | VAF 41/513 reads (8%) | SIFT tolerated (0.35); PolyPhen benign (0.067); catalogued as rs770560181, COSV99280938; called by muse, mutect2
- RHOH | c.68G>A p.R23H | Missense Mutation (SNP) | VAF 108/193 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1159450772, COSV67805187; called by muse, mutect2, varscan2
- SHLD2 | c.545G>C p.C182S | Missense Mutation (SNP) | VAF 87/221 reads (39%) | SIFT tolerated (0.38); PolyPhen benign (0.013); catalogued as COSV53953622; called by muse, mutect2, varscan2
- SLC36A4 | c.241C>G p.P81A | Missense Mutation (SNP) | VAF 57/722 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58395545, COSV99074123; called by muse, mutect2
- SMC1A | c.1535C>A p.P512H | Missense Mutation (SNP) | VAF 46/320 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV59128440; called by muse, mutect2, varscan2
- SSTR4 | c.317C>T p.S106L | Missense Mutation (SNP) | VAF 4/68 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.311); catalogued as rs968716609, COSV99658760; called by muse, mutect2
- SVIL | c.349G>T p.A117S | Missense Mutation (SNP) | VAF 71/562 reads (13%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.997); catalogued as COSV100881149, COSV63441456; called by muse, mutect2, varscan2
- TRAM1 | c.685G>C p.V229L | Missense Mutation (SNP) | VAF 13/128 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.658); catalogued as COSV51597188; called by muse, mutect2, varscan2
- UBQLN3 | c.1960C>G p.Q654E | Missense Mutation (SNP) | VAF 20/148 reads (14%) | SIFT tolerated (0.14); PolyPhen benign (0.001); catalogued as COSV61163602; called by muse, mutect2, varscan2
- ZNF804A | c.2309G>A p.R770Q | Missense Mutation (SNP) | VAF 100/274 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0.081); catalogued as rs750195715, COSV56440604, COSV56454409; called by muse, mutect2, varscan2
- EP300 | c.6516_6517del p.H2172Qfs*37 | Frame Shift Del (DEL) | VAF 27/273 reads (10%) | called by pindel, varscan2
- GTF3C5 | c.1177T>C p.Y393H | Missense Mutation (SNP) | VAF 12/62 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); called by mutect2, varscan2
- KRT31 | c.1065_1078del p.Y356Gfs*76 | Frame Shift Del (DEL) | VAF 50/301 reads (17%) | called by mutect2, pindel, varscan2
- POGK | c.689dup p.N230Kfs*89 | Frame Shift Ins (INS) | VAF 18/86 reads (21%) | called by mutect2, varscan2
- PRAMEF4 | c.1435T>G p.*479Gext*24 | Nonstop Mutation (SNP) | VAF 9/338 reads (3%) | called by muse, mutect2
- ACTN3 | c.1257G>T p.L419= | Silent (SNP) | VAF 4/45 reads (9%) | catalogued as COSV101557876; called by muse, mutect2
- CEACAM1 | c.1005C>G p.T335= | Silent (SNP) | VAF 20/466 reads (4%) | catalogued as rs867429359; called by muse, mutect2
- DNAH11 | c.3210A>G p.E1070= | Silent (SNP) | VAF 128/475 reads (27%) | catalogued as COSV60946670; called by muse, mutect2, varscan2
- FANK1 | c.765G>A p.S255= | Silent (SNP) | VAF 38/236 reads (16%) | catalogued as rs970479200, COSV64126075; called by muse, varscan2
- HIPK4 | c.33C>T p.Y11= | Silent (SNP) | VAF 21/37 reads (57%) | catalogued as rs370981376; called by muse, mutect2, varscan2
- MST1R | c.2430G>A p.V810= | Silent (SNP) | VAF 8/128 reads (6%) | catalogued as COSV99619496; called by muse, mutect2
- NEXMIF | c.795T>A p.I265= | Silent (SNP) | VAF 145/873 reads (17%) | catalogued as COSV99281615; called by muse, mutect2, varscan2
- PCDH15 | c.1221T>C p.S407= | Silent (SNP) | VAF 127/307 reads (41%) | catalogued as COSV57278012; called by muse, mutect2, varscan2
- RAB40A | c.624G>T p.L208= | Silent (SNP) | VAF 15/246 reads (6%) | catalogued as COSV100420994; called by muse, mutect2
- SLC6A4 | c.60T>C p.D20= | Silent (SNP) | VAF 16/81 reads (20%) | catalogued as rs201481422, COSV55565776; called by muse, mutect2, varscan2
- STK25 | c.63C>A p.T21= | Silent (SNP) | VAF 7/67 reads (10%) | catalogued as COSV100346552; called by muse, mutect2
- TAF5 | c.2250T>C p.D750= | Silent (SNP) | VAF 128/285 reads (45%) | catalogued as COSV58915411; called by muse, mutect2, varscan2
- TRMT2A | c.1686C>A p.P562= | Silent (SNP) | VAF 8/110 reads (7%) | catalogued as COSV99350260; called by muse, mutect2
- PTPRK | c.578-1136A>C | Intron (SNP) | VAF 43/145 reads (30%) | called by muse, mutect2, varscan2
